Gene-level copy-number profile of tumor specimen TCGA-AC-A8OQ-01A from TCGA case TCGA-AC-A8OQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 72.6 years (26,535 days).
Specimen TCGA-AC-A8OQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.9e0a88d5-c42a-4094-a44d-f638243a23f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A8OQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e41bd510-0f59-438a-8db2-cf6042032329

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 335; copy number 2: 9,764; copy number 3: 20,754; copy number 4: 12,486; copy number 5: 6,732; copy number 6: 2,558; copy number 7: 3,701; copy number 8: 1,897; copy number 9: 161; copy number 10: 157; copy number 11: 348; copy number 12: 457; copy number 13: 127; copy number 14: 65; copy number 16: 15; copy number 25: 3; copy number 27: 6; copy number 28: 198.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A8OQ-01A-11D-A41E-01): tumor purity 0.22, ploidy 3.99, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,314,110–59,314,800, 1 gene: AC008833.1.
- chr5:172,042,079–172,283,764, 5 genes (within-gene range 0–3): STK10, EFCAB9, UBTD2, AC024561.1, KLF3P1.
- chr13:50,082,169–50,906,856, 1 gene (within-gene range 0–4): DLEU1.
- chr13:50,099,331–50,387,158, 6 genes: RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26, AL158195.1.
- chr14:73,136,418–73,830,135, 31 genes (within-gene range 0–2): PSEN1, AC004858.1, PAPLN, AC004846.1, RNU6-419P, AC004846.2, NUMB, AC005280.3, AC005280.2, AC005280.1, HEATR4, RIOX1, AC005225.1, AC005225.3, ACOT1, NT5CP2, AC005225.2, ACOT2, NT5CP1, AC005225.4, ACOT4, ACOT6, NDUFB8P1, DNAL1, RNU6-240P, AC006146.1, PNMA1, MIDEAS, MIR4505, AC005520.2, LINC02274.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 6,892 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–161,379,358, 823 genes, copy number 7–14 (broad region; genes not listed).
- chr1:162,069,691–162,370,475, 2 genes, copy number 7 (within-gene range 5–7): NOS1AP, AL450163.1.
- chr1:162,316,852–166,856,359, 84 genes, copy number 7 (broad region; genes not listed).
- chr1:201,622,885–201,826,969, 1 gene, copy number 7 (within-gene range 5–7): NAV1.
- chr1:201,688,259–248,919,946, 1,094 genes, copy number 7–13 (within-gene range 5–13) (broad region; genes not listed).
- chr4:55,078,481–57,110,385, 57 genes, copy number 7 (within-gene range 3–7): KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3.
- chr5:58,198–45,895,970, 710 genes, copy number 7 (broad region; genes not listed).
- chr5:57,395,060–57,534,504, 3 genes, copy number 10 (within-gene range 2–10): AC025470.2, SALL4P1, ACTBL2.
- chr6:167,607–78,813,303, 1,711 genes, copy number 7–8 (broad region; genes not listed).
- chr7:112,206,695–112,409,623, 6 genes, copy number 7: ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24.
- chr7:115,935,148–116,663,829, 12 genes, copy number 9: TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT.
- chr8:29,527,312–29,871,661, 8 genes, copy number 7: AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1, AC131254.3.
- chr8:100,957,883–119,108,455, 203 genes, copy number 8–10 (broad region; genes not listed).
- chr8:127,663,280–127,742,951, 3 genes, copy number 16: AC108925.1, CASC11, MYC.
- chr9:107,797,744–108,097,851, 8 genes, copy number 7: RNU6-1064P, RN7SL659P, RPL36AP6, AL162389.1, RNA5SP293, RPS15AP27, AC068050.1, CHCHD4P2.
- chr10:44,712–2,502,200, 39 genes, copy number 8: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1, AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2.
- chr10:5,304,431–5,666,595, 15 genes, copy number 11: RPL26P28, AL683826.1, UCN3, TUBAL3, NET1, CALML5, CALML3-AS1, CALML3, AL732437.1, AL732437.3, AL732437.2, LASTR, AL365356.2, RN7SL445P, ASB13.
- chr10:7,154,120–19,816,278, 192 genes, copy number 8–14 (broad region; genes not listed).
- chr10:23,095,579–23,529,801, 10 genes, copy number 9: MSRB2, YWHAZP3, AL139281.2, PTF1A, C10orf67, AL139281.1, AL606469.1, AL606469.2, OTUD1, AL512603.2.
- chr10:34,109,560–34,815,325, 1 gene, copy number 8 (within-gene range 6–8): PARD3.
- chr10:34,488,583–38,783,108, 88 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr10:48,443,836–53,038,544, 80 genes, copy number 7 (broad region; genes not listed).
- chr11:34,404,663–34,743,199, 9 genes, copy number 9: AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1.
- chr11:80,957,317–81,556,425, 5 genes, copy number 7: AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25.
- chr11:81,842,435–81,987,813, 3 genes, copy number 7: AP002802.2, MIR4300, AP002802.1.
- chr11:88,176,502–89,295,759, 8 genes, copy number 7 (within-gene range 1–7): MIR3166, CTSC, GAPDHP70, AP003120.1, GRM5-AS1, GRM5, RNU6-16P, TYR.
- chr11:90,869,121–98,945,079, 131 genes, copy number 7–9 (broad region; genes not listed).
- chr11:103,402,013–108,498,384, 74 genes, copy number 9–13 (within-gene range 4–13) (broad region; genes not listed).
- chr11:121,674,261–122,025,937, 3 genes, copy number 8 (within-gene range 4–8): AP001977.1, AP001924.1, RNU6-256P.
- chr12:12,049,844–13,387,167, 46 genes, copy number 7 (within-gene range 7–21): BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1, AC092824.1, CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2, CDKN1B, AC008115.3, AC008115.1, APOLD1, MIR613, STX8P1, DDX47, AC007215.1, AC007688.2, RPL13AP20, GPRC5A, MIR614, GPRC5D-AS1, GPRC5D, AC007688.3, AC007688.1, HEBP1, HTR7P1, AC023790.2, AC023790.1, FAM234B, GSG1, EMP1, AC022276.1, LINC01559.
- chr12:52,885,429–53,124,535, 11 genes, copy number 8 (within-gene range 3–8): RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3, IGFBP6, SOAT2.
- chr17:28,755,978–29,057,216, 22 genes, copy number 7 (within-gene range 4–7): FAM222B, RPL31P58, Y_RNA, AC024267.2, ERAL1, AC024267.1, MIR451A, MIR451B, MIR144, MIR4732, FLOT2, AC024267.3, AC024267.6, DHRS13, PHF12, AC024267.4, AC024267.5, PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4.
- chr19:27,638,483–40,629,818, 489 genes, copy number 10–12 (broad region; genes not listed).
- chr20:7,347,451–10,368,776, 31 genes, copy number 14 (within-gene range 3–14): LINC01706, MIR8062, RN7SL547P, AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1, PLCB1, PHKBP1, PLCB1-IT1, RNU105B, AL445567.1, AL445567.2, Metazoa_SRP, PLCB4, LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15.
- chr20:16,272,104–16,864,148, 10 genes, copy number 13 (within-gene range 3–13): KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR, AL121892.1.
- chr20:18,137,228–23,190,419, 108 genes, copy number 8–10 (broad region; genes not listed).
- chr20:24,063,255–25,187,849, 20 genes, copy number 7–13 (within-gene range 2–13): LINC01721, AL110503.1, RNU1-23P, AL158090.1, GAPDHP53, SYNDIG1, AL157413.1, AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, AL035252.5.
- chr20:31,303,212–45,456,934, 400 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr20:50,081,124–64,313,132, 344 genes, copy number 7–16 (within-gene range 6–16) (broad region; genes not listed).
- chr22:45,671,798–46,263,343, 23 genes, copy number 9–25 (within-gene range 5–25): ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1, WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B, PPARA, FP325332.1, CDPF1, PKDREJ.

Autosomal genes at a single copy (total copy number 1): 305. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
